Somatic mutation profile of tumor specimen TCGA-ZG-A9L9-01A (aliquot TCGA-ZG-A9L9-01A-11D-A41K-08) from TCGA case TCGA-ZG-A9L9, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.5 years (22,108 days).
Specimen TCGA-ZG-A9L9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14a0e911-96be-4ae2-b032-9d76b99c0ee4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9L9-10A (Blood Derived Normal), aliquot TCGA-ZG-A9L9-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53cc3cc7-fefd-4bc7-9bac-a1677781f453

The open-access MAF lists 34 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 25, Silent 8, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.3458G>A p.R1153H | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748862206, CM081495, CM117166, COSV55600105; called by muse, mutect2, varscan2
- ADGRA3 | c.3427A>G p.T1143A | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.675); catalogued as rs143592195, COSV99292772; called by muse, mutect2, varscan2
- AFM | c.1447T>C p.C483R | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373381900, COSV99888312; called by muse, mutect2, varscan2
- ASTN1 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1471881730, COSV56079940; called by muse, mutect2, varscan2
- ATG4B | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460485360, COSV100728547; called by muse, mutect2
- CCDC42 | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV99549603; called by muse, mutect2, varscan2
- DNAJC2 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as rs768898513, COSV99971532; called by muse, mutect2, varscan2
- IL36RN | c.31A>G p.M11V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV100697209; called by muse, mutect2, varscan2
- MAN1B1 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1377349742, COSV100857975; called by muse, mutect2, varscan2
- MKLN1 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100759627; called by muse, mutect2, varscan2
- NET1 | c.1616C>T p.S539F (on ENST00000355029 / NM_001047160.3; = p.S485F on NM_005863.5) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.613); catalogued as COSV100742179; called by muse, mutect2, varscan2
- OR2T12 | c.893C>T p.A298V | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV100527440; called by muse, mutect2, varscan2
- PHETA2 | c.385C>A p.R129S | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV100408806; called by muse, mutect2, varscan2
- PLS1 | c.1370A>G p.K457R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); catalogued as COSV100537860; called by muse, mutect2
- PRDM9 | c.631T>G p.F211V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV57003742; called by muse, mutect2, varscan2
- RPS6KB2 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs543512293, COSV100412133; called by muse, mutect2, varscan2
- SCYL2 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100674991; called by muse, mutect2, varscan2
- SPTB | c.3097G>T p.G1033C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.586); catalogued as rs1164403722, COSV101071835; called by muse, mutect2, varscan2
- TTBK1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs201995632, COSV99443361; called by muse, mutect2, varscan2
- TTC3 | c.5121G>C p.Q1707H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as COSV100694865; called by muse, mutect2, varscan2
- UBLCP1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375712033; called by muse, mutect2
- UCP1 | c.817C>A p.P273T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs769316561, COSV99530059; called by muse, varscan2
- XCR1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750354912, COSV100499239; called by muse, mutect2, varscan2
- ZEB2 | c.3224A>G p.N1075S | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100354588; called by muse, mutect2, varscan2
- ZNF567 | c.1438C>T p.P480S (on ENST00000536254 / NM_001322913.1; = p.P449S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1406217848, COSV100658584; called by muse, mutect2, varscan2
- SLC14A2 | c.2541_2562+1del p.X847_splice | Splice Site (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- CACNA1E | c.5067C>T p.N1689= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs377382446; called by muse, mutect2, varscan2
- DLC1 | c.2736C>T p.H912= (on ENST00000276297 / NM_001348081.2; = p.H475= on NM_006094.5) | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99360192; called by muse, mutect2
- LZTS1 | c.897G>A p.P299= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as rs1036580293, COSV99742487; called by muse, mutect2, varscan2
- MYH1 | c.2304T>C p.F768= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as COSV56851568; called by muse, mutect2, varscan2
- MYH13 | c.999G>A p.A333= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs202154427, COSV99351538; called by muse, mutect2, varscan2
- RARS2 | c.756C>T p.Y252= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV101056966; called by muse, mutect2, varscan2
- RNF207 | c.1869G>C p.G623= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV100658181; called by muse, mutect2, varscan2
- RYR2 | c.12636C>T p.N4212= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs1041564863, COSV100766999; called by muse, mutect2, varscan2
